Somatic mutation profile of tumor specimen TCGA-19-2625-01A (aliquot TCGA-19-2625-01A-01D-1495-08) from TCGA case TCGA-19-2625, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.5 years (27,930 days).
Specimen TCGA-19-2625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 196801dc-cb4f-458e-9fa7-80028cf2180b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2625-10A (Blood Derived Normal), aliquot TCGA-19-2625-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ce1ed90-035b-4289-a7e2-e23b7ec571d5

The open-access MAF lists 52 somatic variants for this specimen: 43 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 7, Frame Shift Del 2, In Frame Del 2, Splice Site 2, RNA 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 21/76 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFDN | c.3107A>G p.Y1036C | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60050773; called by muse, mutect2, varscan2
- AREL1 | c.481+1G>A p.X161_splice | Splice Site (SNP) | VAF 26/57 reads (46%) | catalogued as COSV62667358; called by muse, mutect2, varscan2
- ARMC4 | c.1835C>A p.A612E | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59469404; called by muse, mutect2, varscan2
- ATP11C | c.348A>T p.R116S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59569453; called by muse, mutect2, varscan2
- CAND2 | c.1237T>A p.W413R (on ENST00000456430 / NM_001162499.2; = p.W320R on NM_012298.3) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV55992454; called by muse, mutect2
- CD3E | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as rs201840561, COSV62345448, COSV62345905; called by muse, mutect2, varscan2
- CDHR5 | c.1783A>G p.T595A (on ENST00000358353 / NM_001171968.2; = p.T601A on NM_021924.5) | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV57645043; called by muse, mutect2, varscan2
- CENPF | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV65275112, COSV65277252; called by muse, mutect2, varscan2
- EP400 | c.2140C>A p.P714T | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV57780231; called by muse, mutect2, varscan2
- EPRS1 | c.3446A>G p.N1149S | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.928); catalogued as rs372289785; called by muse, mutect2, varscan2
- EZR | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV61455353; called by muse, mutect2, varscan2
- GPR15 | c.1008C>G p.H336Q | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.829); catalogued as COSV52521027; called by muse, mutect2, varscan2
- GSTA4 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775060558, COSV63955849; called by muse, mutect2, varscan2
- HSP90AB1 | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62335741; called by muse, mutect2, varscan2
- IGKV1-17 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as rs759701771; called by muse, mutect2, varscan2
- JMY | c.856T>C p.C286R | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV68661750; called by muse, mutect2, varscan2
- KRTAP24-1 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs200135144, COSV61089693; called by muse, mutect2, varscan2
- MAP3K19 | c.788A>C p.E263A | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59638825, COSV59640871; called by muse, mutect2, varscan2
- MC3R | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54764546; called by muse, mutect2, varscan2
- MED7 | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1358020130, COSV53850446, COSV99644181; called by muse, mutect2, varscan2
- MGME1 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs771609402, COSV66624535; called by muse, mutect2, varscan2
- MUC16 | c.19421A>G p.H6474R | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV67480962; called by muse, mutect2, varscan2
- NPHS2 | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as CM055460, COSV62636024; called by muse, mutect2, varscan2
- OR1G1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.716); catalogued as rs201573244, COSV61030117; called by muse, mutect2, varscan2
- PHF3 | c.3527A>T p.Q1176L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV50329299; called by muse, mutect2, varscan2
- PLCXD1 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58205435; called by muse, mutect2, varscan2
- PPP1R7 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52146116; called by muse, mutect2, varscan2
- PTEN | c.209T>A p.L70H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1513158, CS982332, COSV64301989, COSV64310663; called by muse, mutect2, varscan2
- SCN7A | c.4681G>T p.A1561S | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.979); catalogued as COSV69273477; called by muse, mutect2, varscan2
- SLAMF6 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 141/303 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as COSV63587748; called by muse, mutect2, varscan2
- SPOCD1 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555926182, COSV57095318, COSV57097256; called by muse, mutect2, varscan2
- SQSTM1 | c.838_840del p.E280del | In Frame Del (DEL) | VAF 16/92 reads (17%) | catalogued as rs752009611; called by pindel, varscan2
- TBC1D2 | c.315C>G p.D105E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59787143; called by muse, mutect2, varscan2
- TBX22 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64787003, COSV64787147; called by muse, mutect2
- TGFA | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782074408, COSV54913414, COSV54913742; called by muse, mutect2, varscan2
- THNSL2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59083963, COSV59084283; called by muse, mutect2, varscan2
- ABCC9 | c.1011+1del p.X337_splice | Splice Site (DEL) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- CLCA1 | c.931del p.D312Tfs*15 | Frame Shift Del (DEL) | VAF 45/275 reads (16%) | called by mutect2, pindel, varscan2
- EGR1 | c.121_123del p.L41del | In Frame Del (DEL) | VAF 23/99 reads (23%) | called by pindel, varscan2
- IGKV1D-17 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); called by muse, mutect2
- RB1 | c.492_499del p.L165Dfs*3 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- COL6A2 | c.2409C>T p.D803= | Silent (SNP) | VAF 88/269 reads (33%) | catalogued as rs745800327, COSV56011690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK5 | c.3801C>T p.H1267= | Silent (SNP) | VAF 80/286 reads (28%) | catalogued as rs755820411, COSV52407390; called by muse, mutect2, varscan2
- LDLR | c.1395T>C p.Y465= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV52944949; called by muse, mutect2
- LRIG1 | c.1122G>A p.T374= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs770308260, COSV56245103; called by muse, mutect2, varscan2
- SLC12A7 | c.831G>A p.A277= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs112522540, COSV53760100; called by muse, mutect2, varscan2
- UGT1A1 | c.84G>A p.G28= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV59394402; called by muse, mutect2, varscan2
- WNT10B | c.466C>A p.R156= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV56406016; called by muse, mutect2, varscan2
- C1orf220 | n.417G>A | RNA (SNP) | VAF 22/35 reads (63%) | catalogued as rs1246525815; called by muse, mutect2, varscan2
- THRA | c.1110+89T>G | Intron (SNP) | VAF 20/66 reads (30%) | catalogued as COSV99225664; called by muse, mutect2, varscan2
